TARGET case TARGET-10-PAPDGF — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/d62693cb-a625-5da3-8980-ab36f7c30007

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Precursor B-cell lymphoblastic leukemia: ICD-O-3 morphology code: 9836/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 11.3 years (4,113 days); Year of diagnosis: 2005; Days to last follow up: 3,776 days (10.3 years).

Biospecimens (2 samples)
- Sample TARGET-10-PAPDGF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PAPDGF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
